Somatic mutation profile of cancer-model specimen HCM-SANG-0298-C15-85A (3D Organoid; aliquot HCM-SANG-0298-C15-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0298-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0298-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f6de877-b8b3-4500-a160-9e369e862e79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0298-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0298-C15-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9f7a745-0525-48b2-a75b-0f61f9c2f2b0

The open-access MAF lists 167 somatic variants for this specimen: 124 protein-altering or splice-affecting, 35 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 35, Nonsense Mutation 7, Frame Shift Del 6, 3'UTR 5, Splice Region 2, Intron 2, Frame Shift Ins 1, Nonstop Mutation 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 456/456 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 548/782 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs774625747; called by muse, mutect2
- ALAD | c.165G>A p.R55= | Splice Region (SNP) | VAF 100/470 reads (21%) | catalogued as rs1412547508; called by muse, mutect2, varscan2
- AMY2B | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 95/185 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as rs1355621074; called by muse, mutect2, varscan2
- ANKRD13A | c.1575G>C p.E525D | Missense Mutation (SNP) | VAF 88/407 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV99923883; called by muse, mutect2, varscan2
- APP | c.1832G>C p.G611A | Missense Mutation (SNP) | VAF 259/259 reads (100%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.633); catalogued as rs758117754; called by muse, mutect2, varscan2
- ARMH4 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 302/303 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV50768537; called by muse, mutect2, varscan2
- AURKC | c.374G>A p.R125K (on ENST00000302804 / NM_001015878.2; = p.R91K on NM_003160.3) | Missense Mutation (SNP) | VAF 147/470 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV57140037; called by muse, mutect2, varscan2
- BPI | c.1379C>T p.T460M (on ENST00000262865; = p.T456M on NM_001725.3) | Missense Mutation (SNP) | VAF 324/1326 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs148829027; called by muse, mutect2, varscan2
- C12orf71 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 103/468 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs374505766, COSV70282633; called by muse, varscan2
- CFAP97D2 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 338/981 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs977079646; called by muse, mutect2, varscan2
- COL4A3 | c.4678G>A p.V1560I | Missense Mutation (SNP) | VAF 147/423 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs574102153, COSV67414364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.4411G>A p.G1471S | Missense Mutation (SNP) | VAF 596/596 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750864661, COSV65668331; called by muse, mutect2, varscan2
- DENND6B | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 142/304 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373923302; called by muse, mutect2, varscan2
- DIDO1 | c.6101C>T p.P2034L | Missense Mutation (SNP) | VAF 1200/1606 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs536914525, COSV56634983; called by mutect2, varscan2
- DMD | c.6896A>C p.N2299T | Missense Mutation (SNP) | VAF 235/235 reads (100%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs747055774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK5 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs1459980969; called by muse, mutect2, varscan2
- DPP10 | c.752T>G p.L251R | Missense Mutation (SNP) | VAF 217/312 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59695053; called by muse, mutect2, varscan2
- EPHA6 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 502/502 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as rs1164218979, COSV101061596; called by muse, mutect2, varscan2
- FAT3 | c.7322G>T p.S2441I | Missense Mutation (SNP) | VAF 283/417 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV99971037; called by muse, mutect2, varscan2
- FAT4 | c.7271T>C p.L2424S | Missense Mutation (SNP) | VAF 88/176 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs780471853; called by muse, mutect2, varscan2
- FBXW12 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs775554306; called by muse, mutect2, varscan2
- KCNAB1 | c.719C>T p.S240L (on ENST00000490337 / NM_172160.3; = p.S229L on NM_003471.3) | Missense Mutation (SNP) | VAF 208/208 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748338921, COSV56749073; called by muse, mutect2, varscan2
- KL | c.2009C>G p.A670G | Missense Mutation (SNP) | VAF 141/891 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV66309149; called by muse, mutect2, varscan2
- LHX5 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 332/682 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV55661721; called by muse, mutect2, varscan2
- LRP12 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 341/466 reads (73%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.904); catalogued as COSV99407767; called by muse, mutect2, varscan2
- MYO10 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 315/475 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.81); catalogued as rs762268388, COSV57026787; called by muse, mutect2, varscan2
- NADSYN1 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 407/634 reads (64%) | catalogued as rs372454516, COSV100034749, COSV100034781; called by muse, mutect2, varscan2
- PXDN | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 213/383 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs752428115, COSV99412005, COSV99414014; called by muse, mutect2, varscan2
- RGPD3 | c.2967dup p.D990Rfs*21 | Frame Shift Ins (INS) | VAF 159/506 reads (31%) | catalogued as rs746667934; called by mutect2, varscan2
- RNF215 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 155/331 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs913344524, COSV53176929; called by muse, mutect2, varscan2
- SLC17A6 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 156/157 reads (99%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as COSV54135402; called by muse, mutect2, varscan2
- SULT1C4 | c.907T>C p.*303Qext*1 | Nonstop Mutation (SNP) | VAF 107/290 reads (37%) | catalogued as rs751651312; called by muse, mutect2, varscan2
- TACR3 | c.1255G>C p.D419H | Missense Mutation (SNP) | VAF 137/463 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as rs753738914; called by muse, mutect2, varscan2
- TFCP2L1 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 74/414 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745506190, COSV55288874; called by muse, mutect2, varscan2
- THOP1 | c.250T>G p.F84V | Missense Mutation (SNP) | VAF 118/347 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1321353160; called by muse, mutect2, varscan2
- TMEM132D | c.2908C>T p.R970W | Missense Mutation (SNP) | VAF 174/723 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs558110794, COSV67162419; called by muse, mutect2, varscan2
- ZBTB46 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 411/1769 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV55508677; called by muse, mutect2, varscan2
- ZC3H11A | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 394/569 reads (69%) | SIFT tolerated (0.16); PolyPhen benign (0.363); catalogued as rs1053132373, COSV100142962; called by muse, mutect2, varscan2
- ZFHX4 | c.7373T>G p.L2458R | Missense Mutation (SNP) | VAF 254/1015 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.165); catalogued as COSV50589877, COSV51476909; called by muse, mutect2, varscan2
- ZFHX4 | c.8206C>A p.P2736T | Missense Mutation (SNP) | VAF 60/528 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV99265024; called by mutect2, varscan2
- ZMYND11 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1275904257, COSV59076391; called by muse, mutect2, varscan2
- ZNF17 | c.1669A>G p.T557A | Missense Mutation (SNP) | VAF 179/570 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV56921252; called by muse, mutect2, varscan2
- ZNF582 | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 137/451 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100019035; called by muse, mutect2, varscan2
- ABCE1 | c.1005G>C p.E335D | Missense Mutation (SNP) | VAF 83/165 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALDH18A1 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 136/136 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALKBH1 | c.859del p.H287Tfs*19 | Frame Shift Del (DEL) | VAF 175/395 reads (44%) | called by mutect2, pindel, varscan2
- APC | c.4160del p.C1387Lfs*28 | Frame Shift Del (DEL) | VAF 290/402 reads (72%) | called by mutect2, pindel, varscan2
- ARFGEF3 | c.1732del p.L578Cfs*3 | Frame Shift Del (DEL) | VAF 248/413 reads (60%) | called by mutect2, pindel, varscan2
- ATG16L2 | c.1074_1079delinsGGCTGA p.L359_I360delinsAD | Missense Mutation (ONP) | VAF 129/509 reads (25%) | called by pindel, varscan2*
- AXIN2 | c.1432C>T p.H478Y | Missense Mutation (SNP) | VAF 430/648 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, varscan2
- BTBD3 | c.1070A>C p.K357T | Missense Mutation (SNP) | VAF 177/1099 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CCDC141 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 239/393 reads (61%) | called by muse, mutect2, varscan2
- CCNB1 | c.580G>C p.G194R | Missense Mutation (SNP) | VAF 140/297 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CCNL1 | c.560G>T p.R187M | Missense Mutation (SNP) | VAF 93/171 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCNL1 | c.559A>G p.R187G | Missense Mutation (SNP) | VAF 92/172 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDKN2A | c.194_197del p.L65Pfs*80 | Frame Shift Del (DEL) | VAF 379/387 reads (98%) | called by mutect2, pindel, varscan2
- CILP | c.2127G>T p.E709D | Missense Mutation (SNP) | VAF 111/294 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL3A1 | c.2828C>G p.A943G | Missense Mutation (SNP) | VAF 87/305 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CRIP3 | c.347C>G p.T116R | Missense Mutation (SNP) | VAF 47/473 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CXCL1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 303/423 reads (72%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX3X | c.1234G>A p.E412K (on ENST00000399959; = p.E413K on NM_001356.5) | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- DLG2 | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 187/276 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- EIF3A | c.3064C>A p.L1022M | Missense Mutation (SNP) | VAF 220/726 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- F5 | c.5629T>C p.S1877P | Missense Mutation (SNP) | VAF 85/272 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FMN2 | c.2129G>T p.G710V | Missense Mutation (SNP) | VAF 91/456 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GFRA4 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 240/1485 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GIGYF2 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 111/396 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- H3Y1 | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 445/618 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- HCN4 | c.3359C>G p.P1120R | Missense Mutation (SNP) | VAF 27/802 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2
- HMCN1 | c.13864G>A p.G4622R | Missense Mutation (SNP) | VAF 172/517 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- HTRA1 | c.248G>A p.C83Y | Missense Mutation (SNP) | VAF 709/709 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV2D-30 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 231/641 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- IRAG2 | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- KCNH1 | c.1723G>T p.V575L (on ENST00000271751 / NM_172362.3; = p.V548L on NM_002238.4) | Missense Mutation (SNP) | VAF 195/581 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- KNTC1 | c.6163G>A p.G2055S | Missense Mutation (SNP) | VAF 71/334 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA4 | c.748A>C p.S250R | Missense Mutation (SNP) | VAF 242/304 reads (80%) | SIFT tolerated (0.31); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LBHD1 | c.496G>C p.E166Q (on ENST00000431002 / NM_001367940.1; = p.E140Q on NM_024099.3) | Missense Mutation (SNP) | VAF 173/499 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- LINGO2 | c.113A>C p.N38T | Missense Mutation (SNP) | VAF 254/254 reads (100%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRK2 | c.7351T>C p.F2451L | Missense Mutation (SNP) | VAF 202/474 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LSM14B | c.383C>A p.A128D | Missense Mutation (SNP) | VAF 688/1892 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- MAGEA1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 327/327 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- MRPS34 | c.49C>A p.R17S | Missense Mutation (SNP) | VAF 500/502 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- MTRR | c.400G>T p.G134W (on ENST00000264668; = p.G107W on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/476 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- MUC5B | c.3857_3870del p.I1286Kfs*69 | Frame Shift Del (DEL) | VAF 413/436 reads (95%) | called by mutect2, pindel, varscan2
- MUC6 | c.2035C>A p.R679S | Missense Mutation (SNP) | VAF 362/362 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR7A10 | c.890T>A p.I297K | Missense Mutation (SNP) | VAF 210/312 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.405); called by muse, mutect2
- PANK3 | c.798G>A p.W266* | Nonsense Mutation (SNP) | VAF 109/210 reads (52%) | called by muse, mutect2, varscan2
- PCNT | c.7337G>A p.C2446Y | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- PDE6D | c.238G>C p.V80L | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- PKD2L2 | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 134/265 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLD4 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 160/359 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- POLR3B | c.917del p.I306Kfs*13 | Frame Shift Del (DEL) | VAF 106/510 reads (21%) | called by mutect2, pindel, varscan2
- PPP2R5A | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 97/157 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PRDM13 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 242/608 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, varscan2
- PTGES2 | c.477G>C p.S159= | Splice Region (SNP) | VAF 94/349 reads (27%) | called by muse, mutect2, varscan2
- PUS3 | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 140/510 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RASGRP3 | c.418A>T p.K140* | Nonsense Mutation (SNP) | VAF 397/646 reads (61%) | called by muse, mutect2, varscan2
- RFX1 | c.1713G>T p.Q571H | Missense Mutation (SNP) | VAF 152/449 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- RFX1 | c.1712A>T p.Q571L | Missense Mutation (SNP) | VAF 153/454 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- RGS18 | c.608A>C p.E203A | Missense Mutation (SNP) | VAF 277/421 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RIPK2 | c.660G>C p.W220C | Missense Mutation (SNP) | VAF 80/364 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RRAD | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 261/504 reads (52%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SCARF2 | c.1670C>T p.T557I | Missense Mutation (SNP) | VAF 125/299 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SCN7A | c.645A>C p.K215N | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHOX2 | c.959T>C p.L320P (on ENST00000441443 / NM_006884.3; = p.L344P on NM_003030.4) | Missense Mutation (SNP) | VAF 317/317 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOBP | c.864A>T p.E288D | Missense Mutation (SNP) | VAF 165/412 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SPATA4 | c.331T>A p.W111R | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRGAP1 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 230/495 reads (46%) | called by muse, mutect2, varscan2
- TECTA | c.4674C>A p.D1558E | Missense Mutation (SNP) | VAF 86/291 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- TOP1 | c.1627G>C p.V543L | Missense Mutation (SNP) | VAF 76/743 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TP53BP2 | c.3133G>A p.G1045S (on ENST00000343537 / NM_001031685.3; = p.G916S on NM_005426.2) | Missense Mutation (SNP) | VAF 114/403 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAM1L1 | c.1033A>T p.R345* | Nonsense Mutation (SNP) | VAF 117/436 reads (27%) | called by muse, mutect2, varscan2
- TTC13 | c.1382A>G p.K461R | Missense Mutation (SNP) | VAF 333/477 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TTN | c.25285T>A p.S8429T (on ENST00000591111; = p.S7502T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 250/365 reads (68%) | PolyPhen benign (0); called by muse, mutect2
- TTN | c.14623A>G p.R4875G (on ENST00000591111; = p.R3948G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 176/533 reads (33%) | PolyPhen benign (0.053); called by muse, mutect2, varscan2
- UBE2E3 | c.379-1G>T p.X127_splice | Splice Site (SNP) | VAF 76/290 reads (26%) | called by muse, mutect2, varscan2
- VCPIP1 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 135/518 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- VDR | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 65/517 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- XIRP2 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 74/222 reads (33%) | called by muse, varscan2
- ZFYVE1 | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 321/321 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF208 | c.3277G>T p.A1093S | Missense Mutation (SNP) | VAF 181/515 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ZNF587 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 30/598 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF878 | c.914A>T p.H305L | Missense Mutation (SNP) | VAF 303/475 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC104452.1 | c.951G>A p.A317= | Silent (SNP) | VAF 303/303 reads (100%) | catalogued as rs772179698, COSV56470890; called by muse, mutect2, varscan2
- ADAMTS18 | c.3066C>T p.A1022= | Silent (SNP) | VAF 371/371 reads (100%) | catalogued as rs374112306, COSV99273908; called by muse, mutect2, varscan2
- BMP6 | c.219G>A p.T73= | Silent (SNP) | VAF 412/768 reads (54%) | called by muse, mutect2, varscan2
- C1QL1 | c.117C>T p.G39= | Silent (SNP) | VAF 633/640 reads (99%) | catalogued as rs1442337724; called by muse, mutect2, varscan2
- CFTR | c.3024C>G p.V1008= | Silent (SNP) | VAF 84/204 reads (41%) | called by muse, mutect2, varscan2
- CLVS1 | c.240C>A p.L80= | Silent (SNP) | VAF 173/663 reads (26%) | catalogued as COSV100369725; called by muse, mutect2, varscan2
- COL14A1 | c.3807G>C p.L1269= | Silent (SNP) | VAF 97/569 reads (17%) | called by muse, mutect2, varscan2
- DNAH11 | c.10380G>A p.T3460= | Silent (SNP) | VAF 287/432 reads (66%) | catalogued as rs535847014, COSV60982899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNTTIP1 | c.351C>T p.A117= | Silent (SNP) | VAF 80/688 reads (12%) | called by muse, mutect2, varscan2
- FLG | c.6567A>C p.A2189= | Silent (SNP) | VAF 376/579 reads (65%) | catalogued as rs148841847; called by muse, mutect2, varscan2
- GLT8D1 | c.24C>T p.I8= | Silent (SNP) | VAF 205/205 reads (100%) | called by muse, mutect2, varscan2
- GOLGB1 | c.3519G>A p.K1173= | Silent (SNP) | VAF 130/271 reads (48%) | called by muse, mutect2, varscan2
- GRK1 | c.600C>T p.G200= | Silent (SNP) | VAF 419/1152 reads (36%) | called by muse, mutect2, varscan2
- H4C1 | c.150G>A p.L50= | Silent (SNP) | VAF 294/538 reads (55%) | called by muse, mutect2, varscan2
- HCN1 | c.162C>T p.G54= | Silent (SNP) | VAF 134/456 reads (29%) | called by muse, varscan2
- HEATR1 | c.4191C>T p.P1397= | Silent (SNP) | VAF 128/441 reads (29%) | called by muse, mutect2, varscan2
- HIPK4 | c.339C>T p.I113= | Silent (SNP) | VAF 261/401 reads (65%) | called by muse, mutect2, varscan2
- HMX1 | c.897G>A p.P299= | Silent (SNP) | VAF 310/313 reads (99%) | called by muse, mutect2
- KIF18B | c.1329A>G p.E443= (on ENST00000593135 / NM_001265577.2; = p.E455= on NM_001264573.2) | Silent (SNP) | VAF 25/673 reads (4%) | called by muse, mutect2
- LARP1 | c.1434G>A p.E478= (on ENST00000518297 / NM_033551.3; = p.E401= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 154/342 reads (45%) | called by muse, mutect2, varscan2
- LTBP2 | c.3360C>T p.C1120= | Silent (SNP) | VAF 272/272 reads (100%) | catalogued as rs767331648; called by muse, mutect2, varscan2
- MAGEE1 | c.111C>T p.P37= | Silent (SNP) | VAF 476/480 reads (99%) | catalogued as rs782600060; called by muse, varscan2
- MOBP | c.279G>A p.A93= (on ENST00000420739; = p.A117= on NM_001278322.2) | Silent (SNP) | VAF 658/661 reads (100%) | catalogued as COSV60655075; called by muse, mutect2, varscan2
- NETO1 | c.1314C>T p.S438= | Silent (SNP) | VAF 118/463 reads (25%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.876G>A p.E292= (on ENST00000374531 / NM_001037293.2; = p.E324= on NM_053016.6) | Silent (SNP) | VAF 134/596 reads (22%) | catalogued as rs1380873182, COSV100092860; called by muse, mutect2, varscan2
- PPP2R1B | c.723C>T p.V241= | Silent (SNP) | VAF 146/408 reads (36%) | called by muse, mutect2, varscan2
- RNF25 | c.51C>T p.P17= | Silent (SNP) | VAF 196/303 reads (65%) | called by muse, mutect2, varscan2
- SCAPER | c.87A>C p.I29= | Silent (SNP) | VAF 184/276 reads (67%) | called by muse, mutect2, varscan2
- SIM2 | c.1701C>T p.D567= | Silent (SNP) | VAF 125/125 reads (100%) | called by muse, mutect2, varscan2
- SLC39A8 | c.1375T>C p.L459= | Silent (SNP) | VAF 82/260 reads (32%) | called by muse, mutect2, varscan2
- SP1 | c.363G>A p.K121= (on ENST00000327443 / NM_138473.3; = p.K114= on NM_003109.1) | Silent (SNP) | VAF 177/774 reads (23%) | catalogued as rs1331432816; called by muse, mutect2, varscan2
- TKTL2 | c.1179T>C p.F393= | Silent (SNP) | VAF 370/541 reads (68%) | called by muse, mutect2, varscan2
- ZNF180 | c.249G>A p.R83= | Silent (SNP) | VAF 127/376 reads (34%) | catalogued as rs144535362; called by muse, mutect2, varscan2
- ZNF716 | c.216A>G p.K72= | Silent (SNP) | VAF 79/378 reads (21%) | catalogued as rs1554323436; called by muse, mutect2, varscan2
- ZSCAN5C | c.855C>T p.S285= | Silent (SNP) | VAF 327/532 reads (61%) | catalogued as rs538025264; called by muse, mutect2, varscan2
- ACVR1B | c.1261+30C>A | Intron (SNP) | VAF 179/706 reads (25%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.*1779G>T | 3'UTR (SNP) | VAF 177/1224 reads (14%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.*1778T>G | 3'UTR (SNP) | VAF 181/1228 reads (15%) | called by muse, mutect2, varscan2
- JPT1 | c.*95C>T | 3'UTR (SNP) | VAF 286/286 reads (100%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+27943G>A | Intron (SNP) | VAF 138/315 reads (44%) | catalogued as rs1166817036; called by muse, mutect2, varscan2
- KIR3DX1 | n.1172C>T | RNA (SNP) | VAF 344/511 reads (67%) | catalogued as rs117732069, COSV55601959; called by muse, mutect2, varscan2
- MCF2L | c.*169G>A | 3'UTR (SNP) | VAF 165/1206 reads (14%) | catalogued as rs774808790; called by muse, mutect2, varscan2
- SPRR2B | c.*287G>A | 3'UTR (SNP) | VAF 308/472 reads (65%) | catalogued as COSV100482265; called by muse, mutect2, varscan2
